CCDI case PBCMCT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b7e598d2-6ad0-4d9a-ae54-48f436891e5b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,609 days).

Biospecimens (3 samples)
- Sample 0DV5RR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV5S4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV5SJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
